Somatic mutation profile of tumor specimen C3N-02639-02 (aliquot CPT0182290006) from CPTAC case C3N-02639, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.2 years (21,610 days).
Specimen C3N-02639-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02fdb75c-751d-4c41-afe9-225076d0f9e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02639-31 (Blood Derived Normal), aliquot CPT0182320002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d724064a-4f9f-4c14-9b6a-f3ec32b5dbbc

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Frame Shift Del 2, 3'Flank 1, In Frame Del 1, Intron 1, RNA 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 52/168 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 130/145 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520003, CM156966, COSV52780750, COSV52951418, COSV53606217; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARFGEF1 | c.3772C>T p.R1258W | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242748363, COSV51616244; called by muse, mutect2, varscan2
- CACNA2D3 | c.2428C>T p.R810W | Missense Mutation (SNP) | VAF 96/234 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs771363813, COSV99872810; called by muse, mutect2, varscan2
- CDH13 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 91/106 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs369637512; called by muse, mutect2, varscan2
- FYTTD1 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245493850, COSV54085811; called by muse, mutect2, varscan2
- LRRK1 | c.3409G>A p.V1137I | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs537781752; called by muse, mutect2, varscan2
- MYH6 | c.4151G>A p.R1384Q | Missense Mutation (SNP) | VAF 285/326 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs139265690; called by muse, mutect2, varscan2
- PCDHGA7 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 213/244 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as rs182497799, COSV53892197; called by muse, mutect2, varscan2
- RBM41 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 130/340 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs775670658, COSV99179759; called by muse, mutect2, varscan2
- SPTBN2 | c.6752G>A p.R2251Q | Missense Mutation (SNP) | VAF 92/371 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.768); catalogued as rs763398880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF8 | c.515A>G p.Y172C | Missense Mutation (SNP) | VAF 204/397 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100881229; called by muse, mutect2, varscan2
- TMEM151B | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 230/460 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1385595151, COSV65255419; called by muse, mutect2, varscan2
- TMOD3 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 70/85 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1295421680, COSV100419140; called by muse, mutect2, varscan2
- TOB2 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100548477; called by muse, mutect2, varscan2
- UBQLN2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 256/557 reads (46%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV57739004; called by muse, mutect2, varscan2
- ABCD2 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 52/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ATXN2L | c.2776C>G p.L926V | Missense Mutation (SNP) | VAF 304/365 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- BCR | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 72/88 reads (82%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); called by mutect2, varscan2
- CCDC168 | c.3072T>G p.S1024R | Missense Mutation (SNP) | VAF 77/91 reads (85%) | SIFT tolerated (0.12); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- CDC42BPA | c.2990A>G p.K997R (on ENST00000334218 / NM_001366019.2; = p.K984R on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 99/311 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- INPPL1 | c.1324_1363del p.V442Wfs*6 | Frame Shift Del (DEL) | VAF 85/157 reads (54%) | called by mutect2, pindel
- KIF24 | c.3183_3206del p.D1061_S1068del | In Frame Del (DEL) | VAF 87/158 reads (55%) | called by mutect2, pindel, varscan2
- LRRC70 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 280/317 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- MED14 | c.2727G>T p.Q909H | Missense Mutation (SNP) | VAF 256/597 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MUC16 | c.17033C>T p.T5678I | Missense Mutation (SNP) | VAF 170/208 reads (82%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OTUD5 | c.1513C>T p.R505W | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R1 | c.1112del p.T371Nfs*2 (on ENST00000521381 / NM_181523.3; = p.T101Nfs*2 on NM_181504.4) | Frame Shift Del (DEL) | VAF 70/100 reads (70%) | called by mutect2, pindel, varscan2
- RGS12 | c.157G>C p.A53P | Missense Mutation (SNP) | VAF 93/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHOX | c.750C>G p.I250M | Missense Mutation (SNP) | VAF 325/724 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- SIGLEC10 | c.1024+2_1024+3del p.X342_splice | Splice Site (DEL) | VAF 157/454 reads (35%) | called by pindel, varscan2
- SPATA25 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- UBE4A | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 74/87 reads (85%) | SIFT tolerated (0.75); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- USP24 | c.4152A>T p.E1384D | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D2 | c.453G>A p.Q151= | Silent (SNP) | VAF 361/563 reads (64%) | catalogued as rs773956475; called by muse, mutect2, varscan2
- CPAMD8 | c.4683G>A p.E1561= (on ENST00000651564; = p.E1514= on NM_015692.5) | Silent (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.2337C>T p.F779= (on ENST00000418998 / NM_001377303.1; = p.F689= on NM_015478.7) | Silent (SNP) | VAF 118/258 reads (46%) | catalogued as rs761168787; called by muse, mutect2, varscan2
- LRP1 | c.12153C>T p.A4051= | Silent (SNP) | VAF 51/160 reads (32%) | catalogued as rs544092652; called by muse, mutect2, varscan2
- MAPK6 | c.465A>T p.P155= | Silent (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- NBPF12 | c.2925T>C p.P975= | Silent (SNP) | VAF 108/1324 reads (8%) | called by muse, mutect2
- SLC25A5 | c.171C>T p.C57= | Silent (SNP) | VAF 62/202 reads (31%) | catalogued as rs1463321274, COSV100510393; called by muse, mutect2, varscan2
- SYNJ1 | c.3333G>T p.P1111= | Silent (SNP) | VAF 120/222 reads (54%) | called by muse, mutect2, varscan2
- TAFA1 | c.270G>A p.V90= | Silent (SNP) | VAF 77/186 reads (41%) | called by muse, mutect2, varscan2
- TERT | c.597C>T p.C199= | Silent (SNP) | VAF 356/807 reads (44%) | catalogued as rs751029411, COSV57244363; called by muse, mutect2, varscan2
- TSPYL2 | c.1278C>T p.D426= | Silent (SNP) | VAF 168/407 reads (41%) | catalogued as rs186095471, COSV100966261; called by muse, mutect2, varscan2
- AIRE | c.-47C>T | 5'UTR (SNP) | VAF 163/405 reads (40%) | catalogued as rs1183393068; called by muse, mutect2, varscan2
- ARHGEF12 | c.2380+30T>C | Intron (SNP) | VAF 73/92 reads (79%) | called by muse, mutect2, varscan2
- CPLANE1 | chr5:37165538 C>A | 3'Flank (SNP) | VAF 70/176 reads (40%) | called by muse, mutect2, varscan2
- MKRN9P | n.172A>T | RNA (SNP) | VAF 71/91 reads (78%) | called by muse, mutect2, varscan2
